Surgical pathology report (de-identified scan), TCGA case TCGA-V4-A9E7, project TCGA-UVM (Uveal Melanoma), tissue source site Institut Curie, specimen TCGA-V4-A9E7-01A (Primary Tumor).

[page 1 of 2]
Date of surgery :

Right eye enucleation

Macroscopy

Enucleation specimen measuring 25 mm in diameter with a segment of optic nerve of 7 mm of length. At the section, presence of a pigmented tumor measuring 20 mm of main line in the posterior chamber. Samples have been made for cryopreservation and cytogenetic studies. The specimen has been then included entirely after fixation in 11 blocks.

Miicroscopy

Histological study shows the presence of a malignant melanocytic tumor proliferation developed in the choroid. This tumor is made of epithelioid cells (80%) and also fusiform cells (20%). These cells have marked cytonuclear atypias with nucleolated nuclei. The mitotic index is low (5 mitosis out of 10 high 400 magnification fields) *See path discrepancy form for epithelioid / spindle cell ratio.*

This tumor is developed posterior to the ciliary processes without extension in the ciliary processes and stays distant to the base of implantation of the optic nerve. This tumor infiltrates the internal third of the sclera without extra sclera extension. The optic foramen, the optic nerve and its cut end are free of tumor.

Conclusion

Mixed type (epithelioid and fusiform) choroidal melanoma

Size of the tumor: 20 mm main line

Extension to the internal third of the sclera without extrascleral extension

The optic foramen, the optic nerve and its cut end, the meningeal sheaths are free

CONF ID-0-5
late Melanoma, epithelioid cell 8771/3
Melanoma, epithelioid + spindle cell mixed 8770/3
Site @ Choroid C69.3 9/10 5/10/14

Criteria	hw	12/30/13	Yes	No
HP-AI Discrepancy				
Case is (re)filed				

[page 2 of 2]
TCGA Pathologic Diagnosis Discrepancy Form

V4.00

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS): _____ TSS Identifier: _____ TSS Unique Patient Identifier: _____

Completed By (Interviewer Name on OpenClinica): _____ Completed Date: _____

Diagnosis Information

#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	80% epithelioid cells 20% spindle cells	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF.	61-90% epithelioid cells 1-30% spindle cells	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	The section of the frozen sample used for sending to TCGA corresponds to a section of the tumor where the epithelioid part is predominant. The percentages mentioned on the initial Pathology Report correspond to an average on the whole embedded sections used for establish the Pathology Report.	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director		Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director

Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Principal Investigator Signature

Date

Source: NCI Genomic Data Commons file 0be9a14d-144d-4334-b7d2-98f6c95550ef (TCGA-V4-A9E7.83D9F1B8-553B-47E7-83D9-5663FCEF17A1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).